Somatic mutation profile of tumor specimen HCM-WCMC-0673-C56-86B (aliquot HCM-WCMC-0673-C56-86B-01D-A937-36) from HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-86B: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cb7af60-0844-454e-8ea5-93a08d5f3e53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0673-C56-10A (Blood Derived Normal), aliquot HCM-WCMC-0673-C56-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb4b7ace-d2ac-4df7-a7d6-d8e207a0414b

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, RNA 2, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 206/406 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SMAD4 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 186/187 reads (99%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.869del p.R290Pfs*55 | Frame Shift Del (DEL) | VAF 279/386 reads (72%) | hotspot (GDC flag); catalogued as CM065493, CM993905, COSV52683585, COSV53296796; called by mutect2, pindel, varscan2
- ADAM22 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 141/386 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs368940210; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 197/533 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs749681357, COSV58441412; called by muse, mutect2, varscan2
- AIFM2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 252/502 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs750119679, COSV100325838; called by muse, mutect2, varscan2
- B3GNT2 | c.101A>G p.E34G | Missense Mutation (SNP) | VAF 61/645 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs747635960; called by muse, mutect2
- CTIF | c.377A>T p.H126L | Missense Mutation (SNP) | VAF 12/351 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV56492629; called by muse, mutect2
- ERAS | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 101/958 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1557033040, COSV54432668; called by muse, varscan2
- IGFLR1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV53073857; called by muse, mutect2
- IRGC | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 50/787 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs1388905075, COSV54984510; called by muse, mutect2
- KIAA1210 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 40/848 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV68175546; called by muse, mutect2
- METTL8 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 226/512 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754629409; called by muse, mutect2, varscan2
- OR10K2 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 244/641 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV59222347, COSV59223040; called by muse, mutect2, varscan2
- SLK | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 106/348 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59826566; called by muse, mutect2, varscan2
- SMO | c.1704G>T p.M568I | Missense Mutation (SNP) | VAF 28/645 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.885); catalogued as COSV50837279; called by muse, mutect2
- STAP2 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 21/198 reads (11%) | catalogued as COSV74075507; called by muse, mutect2, varscan2
- STARD9 | c.9842C>T p.P3281L | Missense Mutation (SNP) | VAF 420/816 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs1377609704; called by muse, varscan2
- STON1-GTF2A1L | c.3456G>T p.K1152N | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59128759; called by muse, mutect2
- ULK3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 476/789 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1018512142; called by muse, mutect2, varscan2
- VSTM4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 34/511 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100251737; called by muse, mutect2
- ZNF681 | c.1913G>T p.R638I | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV68074534; called by muse, mutect2, varscan2
- ABCC2 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 178/398 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ACTL6A | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 32/595 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD33B | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 318/775 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, varscan2
- ATP1A2 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 161/380 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- BBX | c.1086A>T p.E362D | Missense Mutation (SNP) | VAF 17/513 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- CDKN2A | c.263_264del p.E88Gfs*31 | Frame Shift Del (DEL) | VAF 471/633 reads (74%) | called by mutect2, pindel, varscan2
- IGSF10 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 50/768 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM4D | c.1199T>G p.L400R | Missense Mutation (SNP) | VAF 228/634 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, varscan2
- KRT38 | c.970A>T p.R324* | Nonsense Mutation (SNP) | VAF 52/778 reads (7%) | called by muse, mutect2
- LARS1 | c.1284+1G>T p.X428_splice (on ENST00000394434 / NM_020117.11; = p.X401_splice on NM_016460.3) | Splice Site (SNP) | VAF 111/275 reads (40%) | called by muse, mutect2, varscan2
- NUFIP1 | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 41/799 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2
- PDPR | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 190/192 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- POU2F1 | c.932T>G p.L311R (on ENST00000541643 / NM_001365848.1; = p.L334R on NM_002697.4) | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2
- POU6F2 | c.722A>T p.Q241L | Missense Mutation (SNP) | VAF 46/998 reads (5%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PRSS54 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 391/391 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- S100PBP | c.919A>T p.R307W | Missense Mutation (SNP) | VAF 23/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMARCA4 | c.4721A>T p.E1574V | Missense Mutation (SNP) | VAF 265/378 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TENM4 | c.6841T>A p.Y2281N | Missense Mutation (SNP) | VAF 44/865 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNPO1 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TRIML1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 51/658 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2
- UBQLN2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 40/790 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.201); called by muse, mutect2
- USP53 | c.940T>A p.W314R | Missense Mutation (SNP) | VAF 32/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR72 | c.335T>G p.I112S | Missense Mutation (SNP) | VAF 121/432 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by mutect2, varscan2
- ZNF573 | c.289T>C p.F97L | Missense Mutation (SNP) | VAF 167/429 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BCL9 | c.1830C>T p.G610= | Silent (SNP) | VAF 172/548 reads (31%) | catalogued as rs1553204848; called by muse, varscan2
- CAPN14 | c.1005G>C p.L335= | Silent (SNP) | VAF 29/699 reads (4%) | called by muse, mutect2
- CELSR2 | c.3519C>T p.T1173= | Silent (SNP) | VAF 48/924 reads (5%) | called by muse, mutect2
- FREM3 | c.834C>T p.D278= | Silent (SNP) | VAF 329/785 reads (42%) | called by muse, varscan2
- HGFAC | c.985C>T p.L329= | Silent (SNP) | VAF 43/692 reads (6%) | called by muse, mutect2
- PAPPA | c.3111A>T p.P1037= | Silent (SNP) | VAF 22/554 reads (4%) | called by muse, mutect2
- SLC26A3 | c.138C>T p.S46= | Silent (SNP) | VAF 202/397 reads (51%) | catalogued as rs750358656; called by muse, mutect2, varscan2
- SVEP1 | c.9T>A p.P3= | Silent (SNP) | VAF 32/412 reads (8%) | called by muse, mutect2
- TMEM255B | c.159G>T p.V53= | Silent (SNP) | VAF 37/844 reads (4%) | catalogued as COSV100943254; called by muse, mutect2
- TYRO3 | c.1336C>T p.L446= | Silent (SNP) | VAF 193/660 reads (29%) | called by muse, mutect2, varscan2
- WDR72 | c.336C>T p.I112= | Silent (SNP) | VAF 119/430 reads (28%) | catalogued as COSV64754524; called by mutect2, varscan2
- AC004837.1 | n.229dup | RNA (INS) | VAF 52/460 reads (11%) | called by mutect2, pindel, varscan2
- COA8 | c.476+886C>T | Intron (SNP) | VAF 20/448 reads (4%) | catalogued as rs915239233; called by muse, mutect2
- DCHS2 | n.8474G>C | RNA (SNP) | VAF 32/658 reads (5%) | catalogued as COSV61772062; called by muse, mutect2
- FUT9 | c.*7911A>G | 3'UTR (SNP) | VAF 244/497 reads (49%) | catalogued as COSV100133553; called by muse, varscan2
